Gene-level copy-number profile of tumor specimen TCGA-N8-A4PL-01A from TCGA case TCGA-N8-A4PL, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Age at diagnosis: 82.3 years (30,069 days).
Specimen TCGA-N8-A4PL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.ea8b5d1c-d157-4d5a-9336-8043f33b6fe8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N8-A4PL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba9833ce-384c-486b-bac2-3018799763b8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,421; copy number 2: 16,579; copy number 3: 17,910; copy number 4: 14,414; copy number 5: 7,142; copy number 6: 903; copy number 7: 122; copy number 8: 171; copy number 9: 47; copy number 10: 71; copy number 12: 13; copy number 20: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N8-A4PL-01A-11D-A28Q-01): tumor purity 0.92, ploidy 3.14, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 450 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:18,363,417–18,468,870, 3 genes, copy number 7: DDX18P3, IMPDH1P9, RNF144B.
- chr12:66,767–7,071,032, 215 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr12:68,674,371–71,667,725, 60 genes, copy number 9–12: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1.
- chr13:90,781,766–94,408,020, 33 genes, copy number 8–20 (within-gene range 6–20): RNU6-75P, LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1, GPC5, AL356118.1, AL162456.1, RNU4ATAC3P, FABP5P4, AL157815.1, GPC5-AS2, AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2.
- chr19:27,638,483–34,127,423, 139 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
